Somatic mutation profile of tumor specimen TCGA-DM-A28A-01A (aliquot TCGA-DM-A28A-01A-21D-A16V-10) from TCGA case TCGA-DM-A28A, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 78.9 years (28,833 days).
Specimen TCGA-DM-A28A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cecf296-0766-45ff-9ab0-512751ae7d39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DM-A28A-10A (Blood Derived Normal), aliquot TCGA-DM-A28A-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da55c4e8-daf2-4c50-9f12-8fc5346378e6

The open-access MAF lists 148 somatic variants for this specimen: 104 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 41, Nonsense Mutation 5, Frame Shift Del 5, 3'UTR 1, RNA 1, In Frame Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1879_1882del p.N627Lfs*2 | Frame Shift Del (DEL) | VAF 54/87 reads (62%) | catalogued as rs1060503360; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BBS2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 93/219 reads (42%) | catalogued as rs567573386, CM114528, COSV55325564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 55/135 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1031T>G p.V344G | Missense Mutation (SNP) | VAF 9/25 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1057519941, COSV55876054, COSV55895486, COSV55974473; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3139C>T p.H1047Y | Missense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); SIFT tolerated (1); PolyPhen benign (0); catalogued as rs121913281, CM126699, COSV55876499, COSV55912376; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ABI3BP | c.1576G>T p.A526S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.625); catalogued as COSV99426823; called by muse, mutect2, varscan2
- ACTR3B | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 69/405 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99754059; called by muse, mutect2, varscan2
- ADAM12 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs374529217, COSV64105363; called by muse, mutect2, varscan2
- AKAP10 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.996); catalogued as COSV99855447; called by muse, mutect2, varscan2
- AKAP6 | c.4774C>T p.R1592* | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as rs772048866, COSV99800852; called by muse, mutect2, varscan2
- AKR1C8P | c.139G>A p.V47I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs555305935; called by muse, mutect2, varscan2
- APCDD1 | c.760C>A p.L254M | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100789962; called by muse, mutect2, varscan2
- BOC | c.1346C>A p.P449H | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV99848721; called by muse, mutect2, varscan2
- BPIFB2 | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs770078142, COSV50064111; called by muse, mutect2, varscan2
- BUD23 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99736616; called by muse, mutect2, varscan2
- CAMTA1 | c.634G>T p.E212* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV100349516; called by mutect2, varscan2
- CARD11 | c.1299C>A p.S433R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV67796598, COSV67800766, COSV67802630; called by muse, mutect2, varscan2
- CASR | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.163); catalogued as rs201338034, COSV56137031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCT3 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747605804, COSV55288859; called by muse, mutect2, varscan2
- CD28 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 86/145 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100142391; called by muse, mutect2, varscan2
- CELF3 | c.902A>G p.N301S | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.3); catalogued as rs746263623, COSV99310320; called by muse, mutect2, varscan2
- CNTFR | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.025); catalogued as rs1221255412, COSV100667517; called by muse, mutect2, varscan2
- CNTN6 | c.345G>T p.K115N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.3); catalogued as rs147658725; called by muse, mutect2, varscan2
- COL27A1 | c.4069C>T p.R1357C | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs745478632, COSV100620697; called by muse, mutect2, varscan2
- CPSF1 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs139115454; called by muse, mutect2, varscan2
- CYB5R3 | c.632A>G p.Q211R | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.877); catalogued as COSV61545376; called by muse, mutect2
- DNAH7 | c.11854G>C p.D3952H | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201407001; called by muse, mutect2, varscan2
- DNAH8 | c.10322G>T p.W3441L | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545327; called by muse, varscan2
- DTWD2 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs769159957, COSV58369087; called by muse, mutect2, varscan2
- FANCA | c.2630C>A p.S877* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as CM161198, COSV99981486; called by muse, mutect2, varscan2
- FGF10 | c.612G>T p.M204I | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV99240574; called by muse, mutect2, varscan2
- FIP1L1 | c.995C>A p.A332E | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.632); catalogued as COSV60995685; called by muse, mutect2
- FRYL | c.4055G>A p.R1352Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs150589993, COSV99976920; called by muse, mutect2, varscan2
- FSTL5 | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100055594; called by muse, mutect2, varscan2
- GALK2 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.744); catalogued as COSV100508904; called by muse, mutect2
- GLI1 | c.110G>T p.G37V | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.526); catalogued as COSV99954135; called by muse, mutect2, varscan2
- GTDC1 | c.1329T>A p.H443Q (on ENST00000344850 / NM_001354361.1; = p.H358Q on NM_024659.6 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.125); catalogued as COSV53991179; called by muse, mutect2, varscan2
- HELB | c.3259A>T p.T1087S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.043); catalogued as COSV99921912; called by muse, mutect2, varscan2
- HIVEP1 | c.5818A>G p.T1940A | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101045136; called by muse, mutect2, varscan2
- IBA57 | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV100812774; called by muse, mutect2, varscan2
- IFIH1 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99718645; called by muse, mutect2, varscan2
- IGF2BP2 | c.1020G>C p.E340D | Missense Mutation (SNP) | VAF 68/140 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV100649144; called by muse, mutect2, varscan2
- ITGA5 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.98); PolyPhen benign (0.115); catalogued as rs369973451, COSV53217784; called by muse, mutect2, varscan2
- JCAD | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs190112050; called by muse, mutect2, varscan2
- KIF26B | c.5758G>A p.E1920K | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs774653307, COSV100831809, COSV63640216; called by muse, mutect2, varscan2
- LAMA5 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 56/62 reads (90%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as rs200037423, COSV53376734; called by muse, mutect2, varscan2
- LAMC2 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.08); catalogued as rs374756027, COSV51452484; called by muse, mutect2, varscan2
- LAP3 | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99884305; called by muse, mutect2, varscan2
- LRP3 | c.1411A>T p.T471S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.925); catalogued as COSV99472260; called by muse, mutect2, varscan2
- MAP3K4 | c.2236C>T p.Q746* | Nonsense Mutation (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100815367; called by muse, mutect2, varscan2
- MC3R | c.764G>T p.W255L | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54763588; called by muse, mutect2, varscan2
- MDN1 | c.3179C>T p.S1060F | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.629); catalogued as COSV101021343; called by muse, mutect2, varscan2
- MED28 | c.95C>A p.A32E | Missense Mutation (SNP) | VAF 35/57 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV99403719; called by muse, mutect2, varscan2
- MSC | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57696401, COSV57696868; called by muse, mutect2, varscan2
- MUC16 | c.7475G>C p.S2492T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); catalogued as COSV101199947, COSV67449743; called by muse, mutect2, varscan2
- NFE2L3 | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs767647938, COSV99283710; called by muse, mutect2, varscan2
- NOM1 | c.2276C>T p.S759L | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs774158292, COSV51983048; called by muse, mutect2, varscan2
- NOVA1 | c.345C>A p.F115L | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as rs185194463, COSV99947626; called by muse, mutect2, varscan2
- NRG3 | c.2008C>T p.R670W (on ENST00000404547 / NM_001370084.1; = p.R646W on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.985); catalogued as rs560914369, COSV64584547; called by muse, mutect2, varscan2
- OAS2 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1039747066, COSV100660152; called by muse, mutect2, varscan2
- OBSCN | c.9419G>T p.R3140L | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV99478094; called by muse, mutect2, varscan2
- PCDHA4 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 48/62 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs576133564, COSV100793445; called by muse, mutect2, varscan2
- PLCG2 | c.2823C>A p.S941R | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as COSV100842336; called by muse, mutect2, varscan2
- PPM1H | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV99955843; called by muse, mutect2, varscan2
- PRDM10 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 144/279 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV100456791; called by muse, mutect2, varscan2
- RANBP17 | c.850G>C p.V284L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101206264; called by muse, mutect2, varscan2
- RGMA | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 52/82 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100224062, COSV61233743; called by muse, varscan2
- RGS3 | c.3149C>T p.A1050V (on ENST00000350696 / NM_001282923.2; = p.A769V on NM_130795.4) | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs374543370; called by muse, mutect2, varscan2
- SEL1L2 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs74764826; called by muse, mutect2, varscan2
- SH3PXD2A | c.2388G>C p.K796N (on ENST00000369774 / NM_001365079.1; = p.K768N on NM_014631.2) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs751249053, COSV100280110; called by muse, mutect2, varscan2
- SLC25A35 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.733); catalogued as COSV99873828; called by muse, mutect2
- SLC30A9 | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs765338091, COSV100048223; called by muse, mutect2, varscan2
- SLIT1 | c.1776C>A p.S592R | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.468); catalogued as COSV99821385; called by muse, mutect2, varscan2
- SLMAP | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs367733735; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD3 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs145200320; called by muse, mutect2, varscan2
- SNX30 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.444); catalogued as rs774859312, COSV100953855; called by muse, mutect2, varscan2
- SRP68 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777223002, COSV100326106; called by muse, mutect2, varscan2
- SRRM4 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs771801140, COSV57414263; called by muse, mutect2, varscan2
- STK31 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV100669411, COSV63456378; called by muse, mutect2, varscan2
- SYCP2L | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as rs773619148, COSV99305179; called by muse, mutect2, varscan2
- SYNE1 | c.8543C>T p.A2848V (on ENST00000367255 / NM_182961.4; = p.A2855V on NM_033071.3) | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs368832347, COSV54949383; called by muse, mutect2, varscan2
- THSD7B | c.1713G>C p.Q571H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as COSV99750879; called by muse, mutect2, varscan2
- TLK2 | c.1085A>G p.Q362R | Missense Mutation (SNP) | VAF 101/281 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV100409211; called by muse, mutect2, varscan2
- TM2D1 | c.59T>A p.V20D | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as COSV53906558; called by muse, mutect2, varscan2
- TMC1 | c.742-1G>T p.X248_splice | Splice Site (SNP) | VAF 34/454 reads (7%) | catalogued as COSV99919464; called by muse, mutect2
- TMEM184A | c.456G>T p.E152D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV99868242; called by muse, mutect2, varscan2
- TNFRSF10D | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100441760; called by muse, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 31/52 reads (60%) | catalogued as rs587780067; called by pindel, varscan2
- TRPV1 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs372945414, COSV99440334; called by muse, mutect2
- TRPV6 | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV100844300; called by muse, mutect2, varscan2
- TTC14 | c.1415G>T p.R472I | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56011762, COSV99868875; called by muse, mutect2, varscan2
- TTLL8 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.65); catalogued as rs748454999, COSV56724210; called by muse, mutect2, varscan2
- UBASH3A | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs777017359, COSV99369609; called by muse, mutect2, varscan2
- UBASH3B | c.1151G>A p.R384Q | Missense Mutation (SNP) | VAF 105/257 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs780762834, COSV52495715; called by muse, mutect2, varscan2
- UFSP1 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs762688142, COSV99574113; called by muse, mutect2
- VPS51 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.808); catalogued as rs780357113, COSV54206944; called by muse, mutect2
- VWF | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1397778191, COSV54621720, COSV99780117; called by muse, mutect2, varscan2
- WDR47 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 88/125 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1245227649, COSV63057766; called by muse, mutect2, varscan2
- ZMIZ1 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1414360518, COSV57901826; called by muse, mutect2, varscan2
- ZNF597 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs781258220, COSV100072012; called by muse, mutect2, varscan2
- AP3M1 | c.558_573del p.D188Nfs*31 | Frame Shift Del (DEL) | VAF 8/81 reads (10%) | called by mutect2, pindel
- ATG2B | c.2232del p.V745Lfs*6 | Frame Shift Del (DEL) | VAF 35/90 reads (39%) | called by mutect2, pindel, varscan2
- SLC35B2 | c.853_855del p.T285del | In Frame Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- ZDHHC8 | c.2213del p.P738Qfs*31 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- ACOT12 | c.1266C>T p.S422= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as COSV100296920; called by muse, mutect2, varscan2
- ADGRB3 | c.3291G>A p.A1097= | Silent (SNP) | VAF 65/156 reads (42%) | catalogued as rs777094686, COSV53238158; called by muse, mutect2, varscan2
- ALOXE3 | c.465C>T p.C155= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs770504844, COSV100559699; called by muse, mutect2, varscan2
- BAZ1A | c.744G>A p.T248= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs1309627549, COSV62411892; called by muse, mutect2, varscan2
- CD37 | c.645C>T p.D215= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100115010; called by muse, mutect2, varscan2
- CHERP | c.21C>T p.P7= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV99550254; called by muse, mutect2, varscan2
- CHRNB3 | c.672G>A p.T224= | Silent (SNP) | VAF 39/50 reads (78%) | catalogued as rs1213299806, COSV51493555; called by muse, mutect2, varscan2
- COL1A2 | c.837C>T p.A279= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as rs1009671128, COSV51956586; called by muse, mutect2, varscan2
- COL6A1 | c.594G>A p.P198= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs376592866; called by mutect2, varscan2
- CSF1R | c.1560C>T p.V520= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs767351282, COSV99641891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM47A | c.1581G>A p.T527= | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as rs777175964, COSV100649898; called by muse, varscan2
- FIG4 | c.1710C>A p.I570= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV100019635; called by muse, mutect2, varscan2
- FPR1 | c.633C>T p.S211= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as rs750529946, COSV59053129, COSV59054554; called by muse, mutect2, varscan2
- FRMPD4 | c.381G>A p.P127= | Silent (SNP) | VAF 30/34 reads (88%) | catalogued as rs753530543, COSV101042682, COSV101042878; called by muse, mutect2, varscan2
- FZD8 | c.1398G>A p.P466= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV101020230; called by muse, mutect2, varscan2
- H2BC4 | c.15C>G p.A5= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as rs368610585, COSV58416792; called by muse, mutect2, varscan2
- HNRNPCL1 | c.282C>T p.N94= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs763260718, COSV58610441; called by muse, mutect2, varscan2
- HSD17B14 | c.51C>A p.G17= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV99612562; called by muse, mutect2, varscan2
- IQSEC3 | c.2631C>T p.F877= (on ENST00000538872 / NM_001170738.2; = p.F574= on NM_015232.1) | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs564741148, COSV100407180; called by muse, mutect2, varscan2
- KCNK9 | c.924C>T p.G308= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs748355464, COSV57279921; called by muse, mutect2, varscan2
- KCNN3 | c.651G>A p.P217= | Silent (SNP) | VAF 52/125 reads (42%) | catalogued as rs764611548, COSV55215290; called by muse, mutect2, varscan2
- KLHDC7A | c.2028C>T p.N676= | Silent (SNP) | VAF 22/32 reads (69%) | catalogued as rs563995322, COSV68770583; called by muse, mutect2, varscan2
- KLK6 | c.75C>T p.G25= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as rs1401187950, COSV59565425; called by muse, mutect2, varscan2
- MPHOSPH8 | c.594G>A p.R198= | Silent (SNP) | VAF 82/241 reads (34%) | catalogued as COSV64055283; called by muse, mutect2, varscan2
- MYH14 | c.195C>T p.F65= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs750733905, COSV51818267, COSV51818516; called by muse, mutect2, varscan2
- MYH6 | c.1251C>T p.S417= | Silent (SNP) | VAF 26/50 reads (52%) | catalogued as rs543839082, COSV100676540; called by muse, mutect2, varscan2
- MYO16 | c.3960C>T p.S1320= | Silent (SNP) | VAF 8/13 reads (62%) | catalogued as rs147869634, COSV100696716; called by muse, mutect2
- PCNX2 | c.5835G>A p.A1945= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as rs180951321, COSV99267648; called by muse, mutect2, varscan2
- PTPRT | c.960C>A p.I320= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV100627283, COSV62006196; called by muse, mutect2, varscan2
- RACGAP1 | c.1347A>G p.T449= | Silent (SNP) | VAF 40/80 reads (50%) | catalogued as rs1381705316, COSV100407765; called by muse, mutect2, varscan2
- RAVER1 | c.234G>T p.L78= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs938696343, COSV99349058; called by muse, mutect2, varscan2
- RELCH | c.3078C>G p.A1026= | Silent (SNP) | VAF 46/56 reads (82%) | catalogued as rs368215665; called by muse, mutect2
- SCN5A | c.5127G>A p.T1709= (on ENST00000333535 / NM_198056.3; = p.T1708= on NM_000335.5) | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as rs747409815, COSV100348372; called by muse, mutect2, varscan2
- SDAD1 | c.858C>G p.A286= | Silent (SNP) | VAF 41/50 reads (82%) | catalogued as COSV62402619; called by muse, mutect2, varscan2
- SHANK2 | c.3381C>T p.P1127= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs113788869, COSV99574031; called by muse, mutect2, varscan2
- SLC6A6 | c.1035T>C p.F345= | Silent (SNP) | VAF 46/129 reads (36%) | catalogued as COSV100692163; called by muse, mutect2, varscan2
- TBC1D13 | c.1029C>T p.A343= | Silent (SNP) | VAF 27/41 reads (66%) | catalogued as rs765024773, COSV56355158, COSV99804669; called by muse, mutect2, varscan2
- TMEM273 | c.195C>T p.D65= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs369394561; called by muse, mutect2, varscan2
- TRIM15 | c.1236G>A p.P412= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as COSV100938828; called by muse, mutect2, varscan2
- UBR4 | c.6336C>T p.S2112= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs766893157, COSV100920802; called by muse, mutect2, varscan2
- USP26 | c.885C>T p.H295= | Silent (SNP) | VAF 38/46 reads (83%) | catalogued as rs371221237, COSV100896632; called by muse, mutect2, varscan2
- DLG4 | chr17:7218271 G>T | 5'Flank (SNP) | VAF 13/17 reads (76%) | catalogued as COSV57237801; called by muse, mutect2, varscan2
- LEKR1 | c.*992C>T | 3'UTR (SNP) | VAF 75/146 reads (51%) | catalogued as rs1256388596, COSV62961514; called by muse, mutect2, varscan2
- TUBB7P | n.27C>T | RNA (SNP) | VAF 27/42 reads (64%) | catalogued as rs782403767; called by muse, mutect2, varscan2
